Surgical pathology report (de-identified scan), TCGA case TCGA-37-4135, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Cureline, specimen TCGA-37-4135-01A (Primary Tumor).

[page 1 of 4]
TCGA-37-4135

Index	Cureline Specimen label	Clinical Site #	Case #				Clinical Diagnosis
1							Lung Cancer
							Lung Cancer

[page 2 of 4]
TCGA-37-4135

Date of procurement	Anatomical Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format	Container	Number of containers	Amount/per container
	Lung	Primary	Tumor	Tissue	OCT	block	1	n/a
	Blood	n/a	Normal	Blood	frozen	tube	1	n/a

[page 3 of 4]
TCGA-37-4135

Unit	Type of Procurement	Histological description (Source)	Grade (source)	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Treatment type
n/a	surgery	Squamous cell carcinoma	3	3	0	0	none
n/a	blood draw	n/a	n/a	n/a	n/a	n/a	none

[page 4 of 4]
Component of treatment (Chemo / Horm Th Details)	Tumor cell %
n/a	71
n/a	n/a

Source: NCI Genomic Data Commons file 215d9013-6dc3-4482-a002-2608f9a32fd4 (TCGA-37-4135.27FD3DE4-A7DA-4DC1-A135-637BCB4B7316.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).